Gene-level copy-number profile of tumor specimen CUPP-B52H-TTM1-A from CCG case CUPP-B52H, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen CUPP-B52H-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 92b37e93-a4a6-40e9-ae88-b9dd77a3ec46.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B52H-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,332 have no estimate.
https://portal.gdc.cancer.gov/files/5736a349-0745-4d0b-83a2-99431b2d8fbc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 21; copy number 2: 121; copy number 3: 6,473; copy number 4: 45,756; copy number 5: 4,117; copy number 6: 946; copy number 7: 283; copy number 8: 384; copy number 9: 147; copy number 10: 16; copy number 11: 7; copy number 12: 2; copy number 13: 2; copy number 14: 2; copy number 15: 4; copy number 16: 2; copy number 21: 3; copy number 22: 1; copy number 25: 1; copy number 31: 1; copy number 33: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:10,365,593–10,366,582, 1 gene: AL138885.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 189 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:40,586,535–40,587,428, 1 gene, copy number 10: RPL5P10.
- chr3:40,603,125–40,605,427, 1 gene, copy number 11: AC122683.1.
- chr3:106,684,388–106,691,320, 2 genes, copy number 10: AC080097.1, Y_RNA.
- chr3:138,482,065–138,485,755, 1 gene, copy number 9: AC022497.1.
- chr3:139,688,403–139,689,342, 1 gene, copy number 9: AC110716.1.
- chr3:145,939,912–145,961,536, 1 gene, copy number 10: AC055758.2.
- chr3:146,059,585–146,105,204, 2 genes, copy number 9 (within-gene range 6–9): AC107021.2, AC107021.1.
- chr3:146,192,335–146,348,480, 2 genes, copy number 11: PLSCR4, AC130509.1.
- chr3:148,991,408–149,031,775, 1 gene, copy number 10 (within-gene range 8–10): GYG1.
- chr3:149,284,782–149,377,692, 4 genes, copy number 9–11 (within-gene range 8–11): AC093001.1, TM4SF18, AC073522.1, TM4SF1.
- chr3:149,462,182–149,736,714, 6 genes, copy number 9–10 (within-gene range 8–10): AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1.
- chr3:149,648,997–149,968,385, 8 genes, copy number 9 (within-gene range 8–10): WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29.
- chr3:150,039,214–150,213,726, 1 gene, copy number 9 (within-gene range 5–9): AC117386.2.
- chr3:150,077,494–150,466,431, 7 genes, copy number 9–10: LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214, TSC22D2.
- chr3:155,760,617–155,761,217, 1 gene, copy number 10: AC104472.2.
- chr3:156,539,553–157,046,129, 7 genes, copy number 9 (within-gene range 6–9): SSR3, TIPARP-AS1, TIPARP, METTL15P1, LINC00886, PA2G4P4, LEKR1.
- chr3:157,146,508–157,160,760, 2 genes, copy number 15: CCNL1, Y_RNA.
- chr3:160,753,428–160,755,142, 1 gene, copy number 9: AC069224.1.
- chr3:164,171,471–164,171,556, 1 gene, copy number 10: MIR1263.
- chr3:167,683,298–167,734,939, 2 genes, copy number 11 (within-gene range 11–13): PDCD10, HMGN1P8.
- chr3:168,927,475–168,928,598, 2 genes, copy number 9: AC092954.1, AC092954.2.
- chr3:171,600,404–173,141,235, 25 genes, copy number 9: PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16.
- chr3:175,938,929–175,941,037, 1 gene, copy number 12: AC104640.1.
- chr10:53,291,072–53,311,065, 1 gene, copy number 9: AC036101.1.
- chr10:57,982,285–57,982,993, 1 gene, copy number 9: MRPS35P3.
- chr10:63,123,929–63,125,587, 1 gene, copy number 9: AL590502.1.
- chr10:64,825,572–64,826,579, 1 gene, copy number 9: ANXA2P3.
- chr10:68,260,557–68,261,499, 1 gene, copy number 31: KRT19P4.
- chr10:69,022,778–69,023,866, 1 gene, copy number 9: ACTBP14.
- chr10:70,929,925–70,932,057, 1 gene, copy number 10: AC073176.1.
- chr10:73,098,044–73,101,297, 1 gene, copy number 10: AL731563.3.
- chr11:67,414,968–67,425,607, 1 gene, copy number 9 (within-gene range 5–9): CARNS1.
- chr11:68,612,899–68,616,711, 1 gene, copy number 10 (within-gene range 5–10): AP003096.1.
- chr15:100,846,604–100,846,767, 1 gene, copy number 15: AC015712.3.
- chr16:83,899,115–83,966,332, 3 genes, copy number 10 (within-gene range 10–12): MLYCD, AC009119.2, OSGIN1.
- chr16:84,009,667–84,045,333, 3 genes, copy number 9 (within-gene range 9–15): SLC38A8, RNA5SP432, AC040169.4.
- chr17:39,461,486–41,019,324, 82 genes, copy number 9–33 (within-gene range 4–33) (broad region; genes not listed).
- chr17:41,054,498–41,055,230, 1 gene, copy number 13: KRTAP2-2.
- chr17:41,117,181–41,118,373, 1 gene, copy number 14: KRTAP4-11.
- chr21:44,994,362–44,995,185, 1 gene, copy number 25: LINC00165.

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
